Somatic mutation profile of tumor specimen TCGA-WN-AB4C-01A (aliquot TCGA-WN-AB4C-01A-11D-A42J-10) from TCGA case TCGA-WN-AB4C, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I.
Specimen TCGA-WN-AB4C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fac50669-a062-42dd-8efe-960e24c6a877.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WN-AB4C-10A (Blood Derived Normal), aliquot TCGA-WN-AB4C-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ae90438-2e50-49a5-a12c-3e868cb717eb

The open-access MAF lists 98 somatic variants for this specimen: 74 protein-altering or splice-affecting, 24 silent.
By variant classification: Missense Mutation 56, Silent 24, Nonsense Mutation 6, Frame Shift Del 3, Splice Site 3, In Frame Del 3, Frame Shift Ins 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAK1 | c.2198A>T p.E733V | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs1490263490, COSV101275923; called by muse, mutect2, varscan2
- AP3B1 | c.255G>T p.K85N | Missense Mutation (SNP) | VAF 143/585 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99670993; called by muse, mutect2, varscan2
- ATP11C | c.5T>G p.F2C | Missense Mutation (SNP) | VAF 55/309 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.586); catalogued as COSV100990178; called by muse, mutect2, varscan2
- ATP1B1 | c.542A>G p.N181S | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100891617; called by muse, mutect2, varscan2
- C16orf46 | c.1061T>A p.V354D | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.246); catalogued as COSV100215201; called by muse, mutect2, varscan2
- CACNG2 | c.98G>C p.W33S | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as COSV100268659; called by muse, mutect2, varscan2
- CADPS2 | c.3797G>A p.R1266H | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1465277551, COSV57349432; called by muse, mutect2, varscan2
- CCR10 | c.742G>C p.V248L | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV99226200; called by muse, mutect2, varscan2
- CDC42BPA | c.4997C>A p.S1666* (on ENST00000334218 / NM_001366019.2; = p.S1653* on NM_003607.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100504273, COSV62018241; called by muse, mutect2
- CDS2 | c.841A>C p.M281L | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100986078; called by muse, mutect2, varscan2
- CKAP5 | c.523T>C p.S175P | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV100370597; called by muse, mutect2, varscan2
- CRTAC1 | c.1138A>C p.I380L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV100085249; called by muse, mutect2, varscan2
- DBP | c.647G>A p.S216N | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV99320548; called by muse, mutect2, varscan2
- DENND1A | c.1919G>C p.S640T | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.322); catalogued as COSV101011871; called by muse, mutect2, varscan2
- DNAJC13 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as COSV99606938; called by muse, mutect2, varscan2
- DNHD1 | c.11792T>A p.V3931E | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.102); catalogued as COSV99599715; called by muse, mutect2, varscan2
- DOC2A | c.27G>A p.M9I | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100451227; called by muse, mutect2, varscan2
- ECI2 | c.295C>T p.L99F (on ENST00000380118 / NM_206836.3; = p.L69F on NM_006117.2) | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.429); catalogued as COSV100326391; called by muse, mutect2, varscan2
- FAM136A | c.75C>G p.I25M | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); catalogued as COSV99231911; called by muse, mutect2, varscan2
- FAM71B | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.042); catalogued as COSV100261863; called by muse, mutect2, varscan2
- FAT1 | c.13569T>A p.Y4523* | Nonsense Mutation (SNP) | VAF 28/147 reads (19%) | catalogued as COSV101499188; called by muse, mutect2, varscan2
- FLCN | c.1539-2A>C p.X513_splice | Splice Site (SNP) | VAF 10/31 reads (32%) | catalogued as COSV99550239; called by muse, mutect2, varscan2
- FMO5 | c.1355T>C p.L452P | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99566849; called by muse, mutect2, varscan2
- FZD8 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV101020193; called by muse, mutect2, varscan2
- GPCPD1 | c.1968G>T p.E656D | Missense Mutation (SNP) | VAF 85/191 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1465149891, COSV100980125; called by muse, mutect2, varscan2
- HSDL2 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV99356733; called by muse, mutect2, varscan2
- IST1 | c.356C>A p.A119D (on ENST00000535424 / NM_001270976.1; = p.A106D on NM_014761.4) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100324574, COSV61709391; called by muse, mutect2, varscan2
- KAT6B | c.5306G>A p.C1769Y | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs751459996, COSV99767636; called by muse, mutect2, varscan2
- KDM3B | c.4234G>C p.G1412R | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100069340; called by muse, mutect2, varscan2
- KNG1 | c.1378G>T p.G460C | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV99405351; called by muse, mutect2, varscan2
- KRT24 | c.696G>T p.L232= | Splice Region (SNP) | VAF 83/499 reads (17%) | catalogued as COSV99231973; called by muse, mutect2, varscan2
- L3MBTL3 | c.1726G>A p.G576S | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100695866; called by muse, mutect2, varscan2
- LGALS3BP | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.074); catalogued as COSV99431468; called by muse, mutect2, varscan2
- LRP1 | c.6241C>G p.L2081V | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99675189; called by muse, mutect2, varscan2
- LZTR1 | c.314G>T p.W105L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53149889, COSV99048795; called by muse, mutect2, varscan2
- MAP7D1 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.553); catalogued as rs756313601, COSV100294327; called by muse, mutect2
- MED1 | c.2044T>A p.S682T | Missense Mutation (SNP) | VAF 65/118 reads (55%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.047); catalogued as COSV100327650; called by muse, mutect2, varscan2
- MED11 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs376931968; called by muse, mutect2, varscan2
- MEGF10 | c.362C>G p.P121R | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99174809; called by muse, mutect2, varscan2
- MRPL39 | c.20G>A p.G7D | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.161); catalogued as COSV100220885; called by muse, mutect2, varscan2
- MXRA5 | c.1558A>G p.I520V | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99476242; called by muse, mutect2, varscan2
- MYT1 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 88/205 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.824); catalogued as COSV60504285; called by muse, mutect2, varscan2
- NOTCH1 | c.1921A>T p.N641Y | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99486475; called by muse, mutect2, varscan2
- OBSCN | c.11626C>A p.Q3876K | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.065); catalogued as COSV99475401; called by muse, mutect2, varscan2
- OCEL1 | c.571A>G p.R191G | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV99285662; called by muse, mutect2, varscan2
- OR51I2 | c.818A>G p.H273R | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1320204634, COSV100413351; called by muse, mutect2, varscan2
- PABPN1 | c.610C>A p.L204M | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99391128; called by muse, mutect2, varscan2
- PKD1L1 | c.8387T>A p.L2796* | Nonsense Mutation (SNP) | VAF 25/88 reads (28%) | catalogued as COSV99219060; called by muse, mutect2, varscan2
- PPP1R12B | c.2336-1G>C p.X779_splice | Splice Site (SNP) | VAF 20/78 reads (26%) | catalogued as COSV99294729; called by muse, mutect2, varscan2
- PSMD2 | c.901C>A p.H301N | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs1333833523, COSV100031636, COSV59530771; called by muse, mutect2, varscan2
- RTKN | c.572T>C p.L191P (on ENST00000272430 / NM_001015055.2; = p.L178P on NM_033046.2) | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99269443; called by muse, mutect2, varscan2
- SEMA3D | c.266A>G p.H89R | Missense Mutation (SNP) | VAF 80/342 reads (23%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as COSV99406222; called by muse, mutect2, varscan2
- SHOC1 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as COSV100597421; called by muse, mutect2, varscan2
- SLC34A2 | c.468G>C p.L156F | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV101158257; called by muse, mutect2, varscan2
- SLC7A2 | c.1600C>A p.L534I (on ENST00000494857 / NM_001370338.1; = p.L573I on NM_003046.6) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV50269592, COSV99134522; called by muse, mutect2, varscan2
- SMC5 | c.2524-1G>A p.X842_splice | Splice Site (SNP) | VAF 34/130 reads (26%) | catalogued as COSV100747009; called by muse, mutect2, varscan2
- SMC5 | c.2524C>A p.Q842K | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.926); catalogued as COSV100747011; called by muse, mutect2, varscan2
- TMEM132A | c.1636G>A p.A546T (on ENST00000453848 / NM_178031.3; = p.A547T on NM_017870.4) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.074); catalogued as COSV99134466; called by muse, mutect2
- TNPO1 | c.2320A>T p.T774S | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.029); catalogued as COSV100473404; called by muse, varscan2
- TRPV5 | c.1537C>A p.Q513K | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54685870, COSV99520266; called by muse, mutect2, varscan2
- TTN | c.42795G>C p.W14265C (on ENST00000591111; = p.W6841C on NM_003319.4) | Missense Mutation (SNP) | VAF 23/111 reads (21%) | PolyPhen probably damaging (0.999); catalogued as COSV100602143; called by muse, mutect2, varscan2
- TUBA8 | c.706T>C p.S236P | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100283094; called by muse, mutect2, varscan2
- UPK3A | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as rs200899354, COSV99343076; called by muse, mutect2, varscan2
- WDTC1 | c.1759C>T p.Q587* (on ENST00000319394 / NM_001276252.2; = p.Q586* on NM_015023.5) | Nonsense Mutation (SNP) | VAF 18/82 reads (22%) | catalogued as COSV60087973; called by muse, mutect2, varscan2
- ZNF302 | c.566C>T p.S189L (on ENST00000627982; = p.S110L on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 129/533 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.05); catalogued as rs764037049, COSV101416449; called by muse, mutect2, varscan2
- ZNF615 | c.1408G>C p.D470H | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.04); catalogued as COSV100943745; called by muse, mutect2, varscan2
- BIRC6 | c.10673_10674dup p.L3560Cfs*21 | Frame Shift Ins (INS) | VAF 14/76 reads (18%) | called by mutect2, pindel, varscan2
- GAPVD1 | c.2994del p.K998Nfs*67 (on ENST00000394104; = p.K1025Nfs*109 on NM_015635.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/69 reads (32%) | called by mutect2, pindel, varscan2
- MAP3K4 | c.800_801del p.E267Afs*11 | Frame Shift Del (DEL) | VAF 49/195 reads (25%) | called by pindel, varscan2
- PON2 | c.17_22del p.A6_V7del | In Frame Del (DEL) | VAF 28/102 reads (27%) | called by mutect2, pindel, varscan2
- PRAMEF14 | c.825del p.K275Nfs*2 | Frame Shift Del (DEL) | VAF 44/186 reads (24%) | called by mutect2, pindel, varscan2
- SCNN1B | c.1471_1473del p.G491del | In Frame Del (DEL) | VAF 35/122 reads (29%) | called by mutect2, pindel, varscan2
- TNPO1 | c.2331_2332dup p.N778Rfs*5 | Frame Shift Ins (INS) | VAF 43/198 reads (22%) | called by pindel, varscan2
- UGT1A1 | c.915_926del p.F305_S309delinsL | In Frame Del (DEL) | VAF 30/104 reads (29%) | called by mutect2, pindel, varscan2
- ANXA13 | c.546G>A p.G182= | Silent (SNP) | VAF 34/119 reads (29%) | catalogued as COSV99146060; called by muse, mutect2, varscan2
- ARHGEF17 | c.2520T>A p.P840= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as COSV99735153; called by muse, mutect2, varscan2
- BRD7 | c.669G>A p.K223= | Silent (SNP) | VAF 42/154 reads (27%) | catalogued as rs150219867; called by muse, mutect2, varscan2
- CASP8AP2 | c.420G>A p.L140= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV99386888; called by muse, mutect2, varscan2
- CDH12 | c.165C>T p.G55= | Silent (SNP) | VAF 45/133 reads (34%) | catalogued as COSV101201969, COSV66444609; called by muse, mutect2, varscan2
- CFAP251 | c.1296C>T p.H432= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV99995876; called by muse, mutect2, varscan2
- CMTM5 | c.345C>A p.V115= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs772122390, COSV100197978; called by muse, mutect2, varscan2
- DDX53 | c.87C>T p.G29= | Silent (SNP) | VAF 186/558 reads (33%) | catalogued as COSV100028777; called by muse, varscan2
- DIAPH3 | c.3135G>A p.K1045= (on ENST00000400324 / NM_001042517.2; = p.K782= on NM_030932.3) | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs1471136559, COSV57367236; called by muse, mutect2, varscan2
- EPS15 | c.474T>A p.S158= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs764497263, COSV100869056; called by muse, mutect2, varscan2
- FBXL5 | c.750T>C p.P250= | Silent (SNP) | VAF 27/116 reads (23%) | catalogued as COSV100377784; called by muse, mutect2, varscan2
- HUNK | c.537G>T p.R179= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV99528252; called by muse, mutect2, varscan2
- ILVBL | c.993C>G p.L331= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV99654704; called by muse, mutect2, varscan2
- ITGA8 | c.1128C>T p.I376= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as COSV100959038, COSV65230363; called by muse, mutect2, varscan2
- MRS2 | c.261T>C p.T87= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV99218816; called by muse, mutect2, varscan2
- NBEAL2 | c.3862C>T p.L1288= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99435266; called by muse, mutect2, varscan2
- NLRP1 | c.2268C>T p.F756= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV99333451; called by muse, mutect2, varscan2
- P2RY10 | c.585G>A p.L195= | Silent (SNP) | VAF 46/146 reads (32%) | catalogued as COSV50683818, COSV99409017; called by muse, mutect2, varscan2
- PPP1CA | c.138T>C p.F46= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV100334910; called by muse, mutect2, varscan2
- RCSD1 | c.669A>T p.A223= | Silent (SNP) | VAF 39/154 reads (25%) | catalogued as COSV100827604; called by muse, mutect2, varscan2
- SLC25A27 | c.312T>A p.G104= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as COSV100992990; called by muse, mutect2, varscan2
- SLC5A2 | c.1305A>T p.V435= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100393093; called by muse, mutect2, varscan2
- TMED5 | c.429T>C p.I143= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV100939141; called by muse, mutect2, varscan2
- ZMIZ2 | c.1281G>A p.V427= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV54808269; called by muse, mutect2, varscan2
